CCDI case PBCAUI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/3c1e8674-ffa5-40c3-bc8c-1c1731a82765

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pituitary adenoma, NOS: ICD-O-3 morphology code: 8272/0; Tissue or organ of origin: Pituitary gland; Age at diagnosis: 16.2 years (5,917 days).

Biospecimens (3 samples)
- Sample 0DMUXD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMUY0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMUZF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
